Surgical pathology report (de-identified scan), TCGA case TCGA-4X-A9FA, project TCGA-THYM (Thymoma), tissue source site Yale University, specimen TCGA-4X-A9FA-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:
MR #:
DOB/Age/Sex:
Visit #:
Submitting Physician:

Accession #:
Taken:
Accessioned:
Adm-Disch Date:
Reported:

Clinical History and Impression:

Swelling, mass or lump in chest
Diabetes mellitus, myasthenia gravis, anterior mediastinal tumor

Specimen(s) Received:

THYMUS

FINAL DIAGNOSIS

THYMUS, THYMECTOMY:

- SPINDLE CELL THYMOMA (TYPE A)
- TUMOR SIZE: 4CM IN GREATEST DIMENSION
- SURGICAL MARGINS ARE NEGATIVE FOR TUMOR
- SEE SYNOPTIC REPORT

SYNOPTIC SUMMARY

Specimen: Thymus
Procedure: Thymectomy
Specimen Integrity: Intact
Specimen Weight: 140 grams
Tumor Size: Greatest dimension:: 4 cm
+ Additional dimension: 3.2 x 2 cm
Histologic Type: Spindle cell thymoma (Type A)
Tumor Extension: Not identified
Margins: Margins uninvolved by tumor
Distance of tumor from closest margin: <1 mm
Treatment Effect: Not applicable
Lymph-Vascular invasion: Not identified
Regional Lymph Nodes: No nodes submitted or found
Pathologic Staging for Thymomas: Stage 1: Grossly and microscopically encapsulated (includes microscopic invasion into, but not through the capsule)

Additional Pathologic Findings: Age-appropriate involution changes
Benign thymic cyst

ICD-O-3
Thymoma, Type A,
malignant 8581/3
Site: Thymus C37.9
#26124/14

Pathologist:

Printed by:

Page 1 of 2

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh, labeled with the patient's name and "thymus, white stitch - right upper lobe, black stitch - surface near pericardium" is an oriented thymectomy specimen oriented by the surgeon and weighing 140 grams. The left lobe measures 24 x 4.5 x 2 cm. The right lobe measures 26 x 5 x 2 cm. The anterior surface of the specimen is inked blue the posterior surface is inked black, the superior margin is inked orange the right margin is inked purple the left margin is inked yellow and the inferior margin is inked red. The specimen is serially sectioned to reveal a tan-pink, gritty lesion with lobulated cut surfaces measuring 4 x 3.2 x 2 cm that abuts the inked anterior and posterior margins and 1 cm from the right margin. The tumor lies 3.5 cm from the superior tip of the right lobe and 17 cm from the inferior tip of the right lobe. The superior aspect of the lesion shows solid cut surfaces. The inferior aspect of the lesion is cystic. Invasion into the fat is not grossly identified. The adjacent thymic parenchyma is tan-yellow, lobulated. Serial sectioning of the specimen does not reveal prominent lymph nodes. Portions of tissue are saved for future ancillary studies. Sections of the lesion are submitted, per diagram, in cassettes 1-9. Random sections of the the uninvolved thymic parenchyma are submitted in cassettes 10-11.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] THYMUS	11	N	(2)	(No Description)
		T	(9)	(No Description)

Printed by:

END OF REPORT

Criteria	hw 12/17/13	Yes	No

Source: NCI Genomic Data Commons file 95c7238a-0fef-47cd-95ea-2a7f5103955c (TCGA-4X-A9FA.DA4437FC-47C4-48B4-A39E-A1BC76B0D9D0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).